TCGA case TCGA-BR-4257 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/da112431-5579-4fd1-a230-9144b359b0e9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 79 years; Vital status: Dead; Days to death: 294 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.3; Tissue or organ of origin: Gastric antrum; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 79.4 years (29,014 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: M0; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 0, day 294.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BR-4257-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 1.5; Shortest dimension: 0.5.
  Slide TCGA-BR-4257-01A-01-BS1: Section location: Bottom; Percent tumor cells: 82; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 3; Percent stromal cells: 10.
  Slide TCGA-BR-4257-01A-01-TS1: Section location: Top; Percent tumor cells: 82; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 3; Percent stromal cells: 10.
- Sample TCGA-BR-4257-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BR-4257-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.4; Intermediate dimension: 1.5; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Anatomic organ subdivision: Antrum/Distal; Cancer procurement city: Kazan; Antireflux treatment: No.
- Follow-up form: New tumor event diagnosis indicator: No; Cause of death: Stomach Cancer.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 294 days; disease-specific survival: event status not recorded, 294 days; progression-free interval: no event (censored), 294 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BR-4257-01A-01D-1130-01): tumor purity 0.54, ploidy 2.65, whole-genome doublings 1.
